Gene-level copy-number profile of tumor specimen TCGA-EM-A1CS-01A from TCGA case TCGA-EM-A1CS, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 55.5 years (20,284 days).
Specimen TCGA-EM-A1CS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-THCA.cb771c37-f102-45e3-9cf8-711b67ea2cef.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EM-A1CS-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2 (sample pair TCGA-EM-A1CS-01A|TCGA-EM-A1CS-10A); ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2131585d-b8a3-4644-97ab-14b59d0e4895

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,376; copy number 2: 58,444.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EM-A1CS-01A-11D-A13V-01): tumor purity 0.8, ploidy 1.99, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,376. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
